Somatic mutation profile of tumor specimen TCGA-66-2754-01A (aliquot TCGA-66-2754-01A-01D-0983-08) from TCGA case TCGA-66-2754, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-66-2754-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e02957ca-aa18-4c56-81b1-fe124f1481d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2754-11A (Solid Tissue Normal), aliquot TCGA-66-2754-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ad7cc83-452f-4261-af45-23056d845cc4

The open-access MAF lists 297 somatic variants for this specimen: 226 protein-altering or splice-affecting, 62 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 62, Nonsense Mutation 14, Splice Site 8, Frame Shift Del 5, Intron 4, 5'Flank 3, Frame Shift Ins 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 14/17 reads (82%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 37/41 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- A2M | c.3685A>T p.T1229S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as COSV59385497; called by muse, mutect2, varscan2
- A2ML1 | c.2737A>T p.T913S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.145); catalogued as COSV55289419; called by muse, mutect2, varscan2
- ACCS | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55457938; called by muse, mutect2, varscan2
- ACSM2B | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61657558; called by muse, mutect2, varscan2
- ACSS3 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs12824208, COSV54089526; called by muse, mutect2, varscan2
- ADAMTS12 | c.2077G>C p.V693L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV61261033; called by muse, mutect2, varscan2
- ADAMTS20 | c.3748G>A p.V1250I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV67130300; called by muse, mutect2, varscan2
- ADCY2 | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57868971; called by muse, mutect2, varscan2
- ADRB2 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs752216112, COSV60005398; called by muse, mutect2, varscan2
- AHNAK2 | c.15700G>A p.E5234K | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.025); catalogued as COSV60913634, COSV60922350; called by muse, mutect2
- AQP12A | c.124-1G>C p.X42_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV61836907; called by muse, mutect2, varscan2
- ARAP2 | c.4145A>G p.N1382S | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58285734; called by muse, mutect2, varscan2
- ARID1B | c.5275G>A p.A1759T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51656461; called by muse, mutect2, varscan2
- ARSI | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763136370, COSV60817209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG4C | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760129724, COSV58605215; called by mutect2, varscan2
- ATP6V0A1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52872511; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2483A>G p.E828G (on ENST00000343619 / NM_001378531.1; = p.E822G on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV52872523; called by muse, mutect2, varscan2
- BACE2 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV57739104; called by muse, varscan2
- BAZ2B | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV58599256; called by muse, mutect2, varscan2
- BCAM | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs200516188; called by muse, mutect2, varscan2
- BCL9L | c.1811C>G p.P604R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.68); catalogued as COSV52683745; called by muse, mutect2, varscan2
- BIRC6 | c.5473G>C p.E1825Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70196159; called by muse, mutect2, varscan2
- BRINP3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV66521072; called by muse, mutect2, varscan2
- C2orf78 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV68517311; called by muse, mutect2, varscan2
- CACNA1B | c.2267C>A p.A756D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201481972, COSV53122870; called by muse, mutect2, varscan2
- CAGE1 | c.1481T>G p.L494R (on ENST00000512086; = p.L358R on NM_205864.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV57076675; called by muse, mutect2, varscan2
- CARF | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV57547356; called by muse, mutect2, varscan2
- CCDC172 | c.320A>T p.K107I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV60937465; called by muse, mutect2, varscan2
- CCDC83 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs199934074, COSV54701393; called by muse, mutect2, varscan2
- CDH12 | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66399725, COSV66446847, COSV66457543; called by muse, mutect2, varscan2
- CDH13 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51811520; called by muse, mutect2, varscan2
- CDH23 | c.4126C>G p.L1376V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.347); catalogued as COSV56458794; called by muse, mutect2, varscan2
- CELSR1 | c.6406A>T p.R2136W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53088216; called by mutect2, varscan2
- CFAP61 | c.843T>A p.S281R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55626675; called by muse, mutect2, varscan2
- CGN | c.3236A>T p.E1079V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54969499; called by muse, mutect2, varscan2
- CHD7 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71109398; called by muse, mutect2, varscan2
- CLSTN2 | c.1405T>C p.Y469H | Missense Mutation (SNP) | VAF 68/76 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754977545, COSV71720373; called by muse, mutect2, varscan2
- CLTRN | c.203+1G>C p.X68_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV66711809; called by muse, mutect2, varscan2
- CNPPD1 | c.1100G>T p.W367L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV55406489; called by muse, mutect2, varscan2
- COL12A1 | c.399C>G p.C133W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59394277; called by muse, mutect2
- COL5A2 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408977; called by muse, mutect2, varscan2
- CPAMD8 | c.4079G>T p.C1360F (on ENST00000651564; = p.C1313F on NM_015692.5) | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV71596456, COSV71597494; called by muse, mutect2, varscan2
- CPXM1 | c.341-2A>T p.X114_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV66045149; called by muse, mutect2, varscan2
- CSRP1 | c.282A>T p.E94D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60636762; called by muse, mutect2, varscan2
- CTSG | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV53535237; called by muse, mutect2, varscan2
- CUL5 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63230081; called by muse, mutect2, varscan2
- CYP4V2 | c.606A>T p.E202D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV66505618; called by muse, mutect2, varscan2
- DDHD2 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68157725; called by muse, mutect2, varscan2
- DDX18 | c.1170T>A p.D390E | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV54306292; called by muse, mutect2, varscan2
- DENND6A | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60768353; called by muse, mutect2, varscan2
- DHRS7C | c.779A>T p.E260V (on ENST00000330255 / NM_001220493.2; = p.E259V on NM_001105571.3) | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV57650440; called by muse, mutect2, varscan2
- DHX35 | c.1871C>G p.T624S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV52669595; called by muse, mutect2, varscan2
- DNAH1 | c.11498A>C p.K3833T | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56233345; called by muse, mutect2, varscan2
- DNAH5 | c.4747G>A p.A1583T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs374072143; called by mutect2, varscan2
- DSCAM | c.2792C>G p.S931C | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV68025327, COSV68036260; called by muse, mutect2, varscan2
- DTX3 | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV54086065; called by muse, mutect2, varscan2
- DTX3L | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs764522063, COSV56143964; called by muse, mutect2, varscan2
- EHD2 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54407955; called by muse, mutect2, varscan2
- ELOVL7 | c.337-2A>T p.X113_splice | Splice Site (SNP) | VAF 51/53 reads (96%) | catalogued as COSV70917925; called by muse, mutect2, varscan2
- EML5 | c.5224T>C p.C1742R (on ENST00000380664; = p.C1750R on NM_183387.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1281430673, COSV61344569; called by muse, mutect2, varscan2
- ENO2 | c.173T>C p.L58S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.572); catalogued as COSV50387951; called by muse, mutect2, varscan2
- EPHB6 | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV63891418; called by muse, mutect2, varscan2
- ERG | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs187337793, COSV55730741; called by muse, mutect2, varscan2
- FAM47A | c.1880A>T p.N627I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV60495943; called by muse, mutect2, varscan2
- FAM47B | c.1478A>C p.D493A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61453444; called by muse, mutect2, varscan2
- FAT3 | c.1852G>T p.G618* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53101313; called by muse, mutect2, varscan2
- FBXO22 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs757686717, COSV57617254; called by muse, mutect2, varscan2
- FCHSD2 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.247); catalogued as COSV60808834; called by muse, mutect2, varscan2
- FGD2 | c.200C>G p.T67R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV51463329; called by muse, mutect2, varscan2
- FMN2 | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV60420428, COSV60452774; called by muse, mutect2, varscan2
- FMO4 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV63000953; called by muse, mutect2, varscan2
- FOXC1 | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66515856; called by muse, mutect2
- FPR3 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV59329160; called by muse, mutect2, varscan2
- GABRA3 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64797741; called by muse, mutect2, varscan2
- GGH | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52650135; called by muse, mutect2, varscan2
- GNAL | c.618C>G p.F206L (on ENST00000269162 / NM_001142339.3; = p.F283L on NM_182978.4) | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as COSV52326254, COSV99304042; called by muse, mutect2, varscan2
- GP1BA | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56699071; called by muse, mutect2, varscan2
- GPR158 | c.1776G>A p.W592* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100893673, COSV66268762; called by muse, mutect2, varscan2
- GRHL1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV61406959; called by muse, mutect2, varscan2
- GRM3 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467658, COSV64470571; called by muse, mutect2, varscan2
- GSTO1 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.898); catalogued as COSV63846587; called by muse, mutect2, varscan2
- HECTD3 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64670029; called by muse, mutect2, varscan2
- HERC6 | c.2886G>C p.Q962H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV52029337, COSV52029651; called by muse, mutect2, varscan2
- HIVEP3 | c.4752A>C p.Q1584H | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56013920; called by muse, mutect2, varscan2
- HLTF | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV59500112; called by muse, mutect2, varscan2
- HOXD11 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751046676, COSV50910853; called by muse, mutect2, varscan2
- HSPA9 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.05); catalogued as COSV51864206; called by muse, mutect2, varscan2
- IGLV3-21 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs544862186; called by muse, mutect2, varscan2
- IL10RA | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV57140296; called by muse, mutect2, varscan2
- IL12RB1 | c.1172del p.P391Rfs*64 | Frame Shift Del (DEL) | VAF 26/28 reads (93%) | catalogued as CD165116; called by mutect2, varscan2
- IL19 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV54283296; called by muse, mutect2, varscan2
- KCNH5 | c.1256A>G p.Y419C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59757903; called by muse, mutect2, varscan2
- KCNJ10 | c.1123C>A p.R375S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV63633400, COSV63634235; called by muse, varscan2
- KCNJ2 | c.615C>G p.D205E | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54660577, COSV54660999, COSV54662110; called by muse, mutect2, varscan2
- KDM2B | c.3829G>A p.D1277N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as COSV65639903; called by muse, mutect2, varscan2
- KEAP1 | c.1632G>T p.W544C | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50275851; called by muse, mutect2, varscan2
- KIAA1549L | c.1882+2T>A p.X628_splice (on ENST00000321505; = p.X925_splice on NM_012194.3) | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV55772431; called by muse, mutect2, varscan2
- KIAA1958 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV61723304; called by muse, mutect2, varscan2
- LCE1C | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV64218357; called by muse, mutect2, varscan2
- LIG3 | c.2192G>A p.G731E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV52007083; called by muse, mutect2, varscan2
- LILRA5 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1569137289, COSV56642369; called by muse, varscan2
- LILRB1 | c.1196C>A p.A399D (on ENST00000427581; = p.A363D on NM_006669.6) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61117437; called by muse, mutect2, varscan2
- LMX1A | c.814T>G p.S272A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV54219699; called by muse, mutect2, varscan2
- MAN2C1 | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51228033; called by muse, mutect2, varscan2
- MAP4K3 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55712142; called by muse, varscan2
- MCUR1 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV63957955; called by muse, mutect2, varscan2
- MEA1 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV55144711; called by muse, mutect2, varscan2
- MERTK | c.2798G>C p.G933A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.182); catalogued as COSV54927773; called by muse, mutect2, varscan2
- METAP2 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51562734; called by muse, mutect2, varscan2
- MTCL1 | c.1937A>C p.E646A (on ENST00000306329 / NM_001378206.1; = p.E286A on NM_015210.4) | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV60405357; called by muse, mutect2, varscan2
- MUC5B | c.5479A>G p.S1827G | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV71591536; called by muse, mutect2, varscan2
- N4BP1 | c.1720G>T p.V574F | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.087); catalogued as COSV52210501; called by muse, mutect2, varscan2
- NCF2 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV62315215; called by muse, varscan2
- NEU2 | c.900C>A p.H300Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV52092493; called by muse, mutect2, varscan2
- NFS1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60764132; called by muse, mutect2, varscan2
- NLRP10 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV60780000; called by muse, mutect2, varscan2
- NLRP3 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60223047; called by muse, mutect2, varscan2
- NPHP1 | c.1881+1G>A p.X627_splice (on ENST00000393272 / NM_207181.4; = p.X628_splice on NM_000272.5) | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as CS080715, CS971832, COSV57208052; called by muse, mutect2, varscan2
- NUP210L | c.3317G>C p.G1106A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55146079; called by muse, mutect2, varscan2
- NXF1 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1444988072, COSV53673523; called by muse, mutect2, varscan2
- OLFM3 | c.922C>T p.Q308* (on ENST00000338858 / NM_001288821.1; = p.Q288* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as COSV58797994; called by muse, mutect2, varscan2
- OR14A16 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.275); catalogued as COSV62926536; called by muse, varscan2
- OR4A16 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59042756; called by muse, mutect2, varscan2
- OR4A16 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV59042764; called by muse, mutect2, varscan2
- OR4D5 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV58306585; called by muse, mutect2, varscan2
- OR52K2 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs778632617, COSV57834995; called by muse, mutect2, varscan2
- OR6N1 | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs566032009, COSV58648043; called by muse, mutect2, varscan2
- OSBPL6 | c.1395+1G>T p.X465_splice | Splice Site (SNP) | VAF 19/32 reads (59%) | catalogued as COSV51915707; called by muse, mutect2, varscan2
- OTUD7B | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.389); catalogued as rs782547858, COSV64914928; called by muse, mutect2, varscan2
- P3H1 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.383); catalogued as COSV52533094; called by muse, mutect2, varscan2
- PARP14 | c.4431G>C p.E1477D | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV71734486; called by muse, mutect2, varscan2
- PBRM1 | c.2965+1G>C p.X989_splice | Splice Site (SNP) | VAF 27/71 reads (38%) | catalogued as COSV56271955, COSV56286695; called by muse, mutect2, varscan2
- PCDHB2 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.02); catalogued as COSV50631980, COSV99164418; called by muse, mutect2, varscan2
- PCDHB9 | c.1447A>C p.N483H | Missense Mutation (SNP) | VAF 112/132 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53377965; called by muse, mutect2, varscan2
- PCSK6 | c.2005G>A p.V669M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV61852093; called by muse, mutect2, varscan2
- PDE8B | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV53736442; called by muse, mutect2, varscan2
- PKHD1 | c.3167C>G p.S1056W | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100585121, COSV61871652; called by muse, mutect2, varscan2
- PLCB1 | c.1947A>T p.R649S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV62047403; called by muse, mutect2, varscan2
- PPIG | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765415648, COSV53642588; called by muse, mutect2, varscan2
- PRAC1 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV51704536; called by muse, mutect2, varscan2
- PRDM9 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV57005401; called by muse, mutect2, varscan2
- PRKN | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV58219160; called by muse, varscan2
- PRRX1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV53413046, COSV99510567; called by muse, mutect2, varscan2
- PSD3 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs573668110, COSV100496176, COSV58967240; called by muse, mutect2, varscan2
- PSEN1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56194139; called by muse, mutect2, varscan2
- PSME3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs371137053; called by muse, mutect2, varscan2
- PTPRZ1 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.467); catalogued as rs1259413200, COSV66435084; called by muse, mutect2, varscan2
- PTPRZ1 | c.5247C>A p.D1749E | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV66435088; called by muse, varscan2
- PURA | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495702, COSV58762090; called by muse, mutect2
- PXDNL | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.14); catalogued as COSV62485832; called by muse, mutect2, varscan2
- PZP | c.3550G>C p.D1184H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs915207257, COSV54358671; called by muse, varscan2
- QSER1 | c.1890A>C p.K630N (on ENST00000399302; = p.K759N on NM_001076786.3) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV67900219; called by muse, mutect2, varscan2
- RAB3B | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); catalogued as rs779381327, COSV63228342; called by muse, mutect2, varscan2
- RAD51B | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV66846760; called by muse, mutect2, varscan2
- RAG2 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.65); catalogued as COSV57557349; called by muse, mutect2, varscan2
- RAPGEFL1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52862995; called by muse, mutect2, varscan2
- RB1 | c.1927A>T p.K643* | Nonsense Mutation (SNP) | VAF 18/27 reads (67%) | catalogued as COSV57304094; called by muse, mutect2, varscan2
- RECQL4 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1359100897, COSV52878992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGPD1 | c.3995C>G p.S1332C (on ENST00000409776; = p.S1340C on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as COSV101233590; called by mutect2, varscan2
- RPL10L | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV53559400, COSV53561161; called by muse, mutect2, varscan2
- RSPH3 | c.619A>T p.T207S (on ENST00000252655; = p.T65S on NM_031924.8) | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV51922131; called by muse, mutect2, varscan2
- RTN1 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50721799; called by muse, mutect2, varscan2
- RTN1 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745478215, COSV50721811; called by muse, varscan2
- RTN4IP1 | c.937A>T p.I313L | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV64805273; called by muse, mutect2, varscan2
- RYR2 | c.13010C>A p.P4337H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773113, COSV63680248, COSV63701662; called by muse, mutect2, varscan2
- SCN2A | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV51838617; called by muse, mutect2, varscan2
- SERPINA4 | c.347A>C p.D116A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV54069712; called by muse, mutect2, varscan2
- SETD1A | c.3883C>T p.H1295Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.439); catalogued as COSV52686972; called by muse, mutect2, varscan2
- SLC10A2 | c.692C>A p.T231K | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV55358384; called by muse, mutect2, varscan2
- SLC26A6 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV50849701; called by muse, mutect2, varscan2
- SLC35F1 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64502031; called by muse, mutect2, varscan2
- SLC5A1 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as CD962160, COSV56684867; called by muse, varscan2
- SLC6A19 | c.1619T>C p.L540P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs971321082, COSV57250769; called by muse, mutect2, varscan2
- SLC8A1 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV60478143; called by muse, mutect2, varscan2
- SLC9A5 | c.1715T>G p.L572R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV55361657; called by muse, mutect2, varscan2
- SMCHD1 | c.644A>T p.H215L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.551); catalogued as COSV55255643; called by muse, mutect2, varscan2
- SMCHD1 | c.3898A>G p.I1300V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.847); catalogued as COSV55255664; called by muse, mutect2
- SNRNP200 | c.3934C>G p.L1312V | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV60489305; called by muse, mutect2, varscan2
- SORCS1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53845046; called by muse, mutect2, varscan2
- SPINT1 | c.684C>A p.D228E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.381); catalogued as COSV59801722; called by muse, mutect2, varscan2
- SRCAP | c.4537C>A p.P1513T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV52671260; called by muse, mutect2, varscan2
- STK10 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as rs754257512, COSV51573372; called by muse, mutect2, varscan2
- TDRD3 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 39/51 reads (76%) | catalogued as COSV52155880; called by muse, mutect2, varscan2
- TEAD2 | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV60544175; called by muse, mutect2, varscan2
- TEX14 | c.3118G>A p.E1040K (on ENST00000240361 / NM_001201457.2; = p.E1034K on NM_031272.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV53615254; called by muse, mutect2, varscan2
- TFRC | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772641140, COSV100786409, COSV64053836; called by muse, mutect2, varscan2
- TG | c.8061C>A p.D2687E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.044); catalogued as rs530272451, COSV55073175; called by muse, varscan2
- THOC1 | c.1618A>G p.I540V | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.5); catalogued as COSV55274980; called by muse, mutect2, varscan2
- TJP1 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 40/51 reads (78%) | catalogued as COSV62041320; called by muse, mutect2, varscan2
- TM4SF5 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.389); catalogued as COSV54496389; called by muse, mutect2, varscan2
- TMED3 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.157); catalogued as rs755717811, COSV55302635; called by muse, mutect2, varscan2
- TMEM132D | c.1735G>C p.V579L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67159965; called by muse, mutect2, varscan2
- TMEM132D | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1328208259, COSV70602054; called by muse, mutect2, varscan2
- TMPRSS9 | c.2521G>T p.E841* (on ENST00000648592; = p.E807* on NM_182973.2) | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV53114148; called by muse, mutect2, varscan2
- TMTC1 | c.1644C>A p.N548K (on ENST00000539277 / NM_001193451.2; = p.N440K on NM_175861.3) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.194); catalogued as COSV55479640; called by muse, mutect2, varscan2
- TNC | c.4902C>G p.D1634E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.239); catalogued as rs761059514, COSV60783857; called by muse, mutect2, varscan2
- TOP2A | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV70732417; called by muse, mutect2, varscan2
- TP53BP1 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV55499726; called by muse, mutect2, varscan2
- TROAP | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57743760; called by muse, mutect2, varscan2
- TSTD2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV52246817; called by muse, mutect2, varscan2
- TTN | c.68888C>A p.P22963H (on ENST00000591111; = p.P15539H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | PolyPhen probably damaging (0.912); catalogued as COSV60000755; called by muse, mutect2, varscan2
- TTN | c.2396C>T p.T799M (on ENST00000591111; = p.T753M on NM_003319.4) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | PolyPhen benign (0.107); catalogued as rs149061352, COSV60000823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs533930379, COSV53469674; called by muse, varscan2
- UBR5 | c.5536A>G p.M1846V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV55284915; called by muse, mutect2, varscan2
- UPK3A | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.242); catalogued as COSV53414267; called by muse, mutect2, varscan2
- USP13 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55864929; called by muse, mutect2, varscan2
- UTP25 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs140967197; called by muse, mutect2, varscan2
- VPS13B | c.4318G>C p.D1440H | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62139250; called by muse, mutect2, varscan2
- ZBED9 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV71729344; called by muse, mutect2, varscan2
- ZBP1 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 125/219 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100473710, COSV59061404; called by muse, mutect2, varscan2
- ZNF311 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as COSV65853043; called by muse, mutect2, varscan2
- ZNF320 | c.1138A>C p.T380P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67087979; called by muse, mutect2, varscan2
- ZNF618 | c.2219C>T p.T740M (on ENST00000374126 / NM_001318042.2; = p.T647M on NM_133374.2) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs375702223; called by muse, varscan2
- ZSCAN22 | c.1176C>G p.S392R | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV61638993; called by muse, mutect2, varscan2
- BOC | c.2654_2655insCA p.K885Nfs*53 | Frame Shift Ins (INS) | VAF 15/122 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.7175G>A p.C2392Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FERD3L | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by mutect2, varscan2
- GLUD1 | c.992del p.G331Vfs*49 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- GNAO1 | c.493dup p.A165Gfs*37 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- MUC2 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- PIGW | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SRSF1 | c.556_557del p.E186Nfs*7 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by pindel, varscan2
- TRBV20-1 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ZNF98 | c.648del p.A218Pfs*41 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- AASDHPPT | c.150G>A p.Q50= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs771376653, COSV53788882; called by muse, mutect2, varscan2
- ABL1 | c.3288G>A p.E1096= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV59329869; called by muse, mutect2, varscan2
- AGTR2 | c.870C>T p.C290= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV64156392; called by muse, mutect2, varscan2
- AHNAK | c.354G>A p.Q118= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57211342; called by muse, mutect2
- ALMS1 | c.8562A>G p.L2854= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV52508167; called by muse, mutect2, varscan2
- BRAF | c.267A>G p.L89= | Silent (SNP) | VAF 43/53 reads (81%) | catalogued as COSV56147956; called by muse, mutect2, varscan2
- CACNA1D | c.5778G>A p.E1926= (on ENST00000350061 / NM_001128840.3; = p.E1946= on NM_000720.4) | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV55444505; called by muse, mutect2, varscan2
- CD63 | c.513T>C p.I171= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV57676298; called by muse, mutect2, varscan2
- CHRNA10 | c.174C>T p.T58= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV51709278; called by muse, mutect2, varscan2
- CNGB3 | c.90C>G p.G30= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV60688466; called by muse, mutect2, varscan2
- CNTNAP5 | c.1149C>A p.T383= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV70482697, COSV70488364; called by muse, mutect2, varscan2
- COL6A3 | c.1875G>A p.R625= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55086999; called by muse, mutect2, varscan2
- COP1 | c.1740C>G p.V580= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58165975, COSV58176399; called by muse, mutect2, varscan2
- CTTNBP2 | c.1533A>G p.G511= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV50396820; called by muse, mutect2, varscan2
- DAPK1 | c.2703G>A p.E901= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV63786773; called by muse, mutect2, varscan2
- DRD1 | c.621G>T p.V207= | Silent (SNP) | VAF 73/86 reads (85%) | catalogued as rs752538302, COSV67104478; called by muse, mutect2, varscan2
- EXOC3L4 | c.1971C>T p.D657= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs766402144, COSV66295460; called by muse, mutect2, varscan2
- FAT1 | c.8088G>A p.P2696= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs372629114; called by muse, mutect2, varscan2
- GABRA4 | c.1419T>C p.A473= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV51926254; called by muse, mutect2, varscan2
- GRM5 | c.120C>G p.L40= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1565351095, COSV59601690; called by muse, mutect2, varscan2
- HECW1 | c.2322C>A p.A774= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV67827373; called by muse, mutect2, varscan2
- HLA-E | c.870C>T p.P290= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs370435793; called by muse, mutect2, varscan2
- IRX1 | c.388C>A p.R130= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1334101890, COSV57359031; called by muse, mutect2, varscan2
- ITGAX | c.1920G>A p.R640= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51644866; called by muse, mutect2, varscan2
- KCNJ2 | c.273T>G p.A91= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV54660988, COSV54661803; called by muse, mutect2, varscan2
- KCNK4 | c.336C>A p.R112= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100107859, COSV60453897; called by muse, mutect2, varscan2
- MAST4 | c.6696C>T p.L2232= (on ENST00000403625 / NM_001164664.2; = p.L2043= on NM_015183.3) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs757679298, COSV55122573; called by muse, mutect2, varscan2
- MUC16 | c.29007T>G p.S9669= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV67461218; called by muse, mutect2, varscan2
- MYL9 | c.468C>T p.Y156= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1233523772, COSV54072317; called by muse, mutect2, varscan2
- NEDD4L | c.1362A>G p.L454= (on ENST00000400345 / NM_001144967.3; = p.L434= on NM_015277.6) | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV56843505; called by muse, mutect2, varscan2
- NELL1 | c.2400T>C p.C800= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54257343; called by muse, mutect2, varscan2
- OR4C15 | c.885T>A p.S295= (on ENST00000314644; = p.S241= on NM_001001920.2) | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV58952361; called by muse, mutect2, varscan2
- OR4N5 | c.570C>A p.T190= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs376173734; called by muse, mutect2, varscan2
- OR4S1 | c.675C>T p.S225= | Silent (SNP) | VAF 69/103 reads (67%) | catalogued as COSV60678956; called by muse, mutect2, varscan2
- OR7A17 | c.297C>A p.T99= | Silent (SNP) | VAF 78/115 reads (68%) | catalogued as COSV59414179, COSV59414412; called by muse, mutect2, varscan2
- PANX1 | c.351G>A p.A117= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs969347589, COSV57133377; called by muse, mutect2, varscan2
- PCDH19 | c.3432G>A p.K1144= (on ENST00000373034 / NM_001184880.2; = p.K1096= on NM_020766.3) | Silent (SNP) | VAF 56/60 reads (93%) | catalogued as COSV55261461; called by muse, mutect2, varscan2
- PDZK1IP1 | c.105C>T p.I35= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1343099761, COSV53743920; called by muse, mutect2, varscan2
- PHC1 | c.1083C>G p.P361= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV70417816; called by muse, mutect2, varscan2
- PLCG1 | c.3669C>T p.F1223= (on ENST00000373271 / NM_182811.2; = p.F1224= on NM_002660.3) | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV54817742; called by muse, mutect2, varscan2
- PNMA8B | c.399G>A p.S133= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV66536399; called by muse, mutect2, varscan2
- PRAMEF2 | c.759A>T p.G253= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV53574666; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.816G>A p.L272= (on ENST00000421990 / NM_001136042.2; = p.L254= on NM_025267.3) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64182550; called by muse, mutect2, varscan2
- PTPRN | c.2349G>A p.T783= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs376416230; called by muse, mutect2, varscan2
- RADX | c.60G>T p.P20= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as COSV65318358, COSV65320264; called by muse, mutect2, varscan2
- RNF145 | c.267C>T p.L89= (on ENST00000424310 / NM_001199383.2; = p.L117= on NM_144726.2) | Silent (SNP) | VAF 50/174 reads (29%) | catalogued as COSV50865866; called by muse, mutect2, varscan2
- SEMA7A | c.1320G>A p.V440= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV56090119; called by muse, mutect2, varscan2
- SERPINA10 | c.1005T>C p.V335= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV56228115; called by muse, mutect2, varscan2
- SNX9 | c.1434G>T p.V478= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV67583919; called by mutect2, varscan2
- TEX19 | c.24G>A p.R8= | Silent (SNP) | VAF 88/127 reads (69%) | catalogued as COSV61017102; called by muse, mutect2, varscan2
- TG | c.8208G>A p.Q2736= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV55073182; called by muse, mutect2, varscan2
- TMEM74B | c.519G>A p.L173= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV67891879; called by muse, mutect2, varscan2
- TMEM94 | c.1396C>A p.R466= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV58594989, COSV58601566; called by muse, mutect2, varscan2
- TNIP3 | c.153G>T p.L51= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV50247175; called by muse, mutect2, varscan2
- UBR2 | c.1629A>G p.K543= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs1254230773, COSV65749848; called by muse, mutect2, varscan2
- UGGT2 | c.3660G>A p.L1220= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV65074133, COSV65080698; called by muse, mutect2, varscan2
- UGP2 | c.387G>A p.L129= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV61427975; called by muse, mutect2, varscan2
- USP11 | c.1644C>T p.H548= (on ENST00000218348; = p.H505= on NM_001371072.1) | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs896972357, COSV54473389; called by muse, mutect2, varscan2
- USP47 | c.4077A>G p.A1359= (on ENST00000399455 / NM_001372095.1; = p.A1271= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV59694061; called by muse, mutect2, varscan2
- ZHX2 | c.645C>T p.T215= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs184731017, COSV58712449; called by muse, mutect2, varscan2
- ZNF416 | c.192A>T p.I64= | Silent (SNP) | VAF 79/125 reads (63%) | catalogued as COSV52184044; called by muse, mutect2, varscan2
- ZNF618 | c.2196C>T p.L732= (on ENST00000374126 / NM_001318042.2; = p.L639= on NM_133374.2) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs780885544, COSV55920103; called by muse, varscan2
- AL132655.6 | chr20:58840472 G>C | 5'Flank (SNP) | VAF 16/66 reads (24%) | catalogued as COSV58333109; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415314 A>T | 5'Flank (SNP) | VAF 19/54 reads (35%) | catalogued as rs758421829, COSV52567369; called by muse, mutect2, varscan2
- NCAPD2 | c.262+111G>A | Intron (SNP) | VAF 34/124 reads (27%) | catalogued as rs760296122, COSV100216958; called by muse, mutect2, varscan2
- OR51T1 | chr11:4881884 G>A | 5'Flank (SNP) | VAF 25/47 reads (53%) | catalogued as COSV59024989; called by muse, mutect2
- POLR2F | c.453-14978C>T | Intron (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1195T>C | RNA (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SSX5 | c.70-199C>A | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100308691; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1493G>A | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100313829, COSV60363694; called by muse, mutect2, varscan2
- VSIG4 | chrX:66018930 G>A | 3'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
